Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4308, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4308-01A (Primary Tumor).

FINAL DIAGNOSIS:

PARTS 1

AND 2: COLON, SIGMOID AND RECTUM, RESECTION --

- A. INVASIVE WELL TO MODERATELY DIFFERENTIATED ADENOCARCINOMA, MEASURING 5.5 CM IN GREATEST DIMENSION, INVADING THROUGH MUSCULARIS PROPRIA INTO PERICOLONIC ADIPOSE TISSUE (EXTENDING TO WITHIN LESS THAN 1 MM TO SEROSAL SURFACE).
- B. NO DEFINITE PERINEURAL INVASION IS SEEN.
- C. PROXIMAL AND DISTAL SURGICAL RESECTION MARGINS NEGATIVE FOR TUMOR.
- D. MULTIPLE REGIONAL LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA (3/14).
- E. PATHOLOGIC STAGE: pT3, N1, Mx.

MICROSCOPIC:

SYNOPTIC DATA - PRIMARY COLON AND RECTAL TUMORS

SPECIMEN TYPE: Sigmoidectomy
SPECIMEN LENGTH: 11.5 cm
TUMOR SITE: Sigmoid colon
TUMOR CONFIGURATION: Infiltrative
TUMOR SIZE: Greatest dimension: 5.5 cm
Additional dimensions: 4.5 cm
INTACTNESS OF MESORECTUM: Not applicable
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM): pT3c/d

pN1

Number of nodes examined: 14

Number of nodes involved: 3

pMX

MARGINS

Proximal margin uninvolved by invasive carcinoma

Distal margin uninvolved by invasive carcinoma

Circumferential (radial) margin - Not applicable

Mesenteric margin uninvolved by invasive carcinoma

ANGIOLYMPHATIC INVASION:

Present

PERINEURAL INVASION:

Absent

TUMOR BORDER CONFIGURATION:

Infiltrating

TUMORAL LYMPHOCYTIC RESPONSE:

Mild to moderate

ADDITIONAL PATHOLOGIC FINDINGS:

None identified

TCGA-AZ-4308

Source: NCI Genomic Data Commons file 964fbe7a-d770-4ccf-a497-ec3506ce0185 (TCGA-AZ-4308.ED3AB172-0CB7-4AF2-827D-65A566BF7C66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).